Surgical pathology report (de-identified scan), TCGA case TCGA-IW-A3M6, project TCGA-SARC (Sarcoma), tissue source site Cedars Sinai, specimen TCGA-IW-A3M6-01A (Primary Tumor).

[page 1 of 4]
UUIID: 4C967429-23AE-4393-B39E-B939AC1AC399

Pathologist:
Assistant:
Date of Procedure:
Date Received:

Ordering M.D.:
Copies to:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHERECTOMY:

- Fallopian tube with tubo-ovarian adhesion
- Paratubal cysts lined by benign serous epithelium (hydatids of Morgagni)
- Ovary with atrophic changes, a cystic epithelial inclusion, and serosal adhesions
- Paraovarian cystic and solid Walthard rests
- No evidence of metastatic tumor

B, C. UTERUS, BIOPSY OF MASS LESION AND TOTAL ABDOMINAL HYSTERECTOMY, AND FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- Primary uterine leiomyosarcoma (see comment)
- Estimated maximum tumor size: 13.5 cm (borders not well delineated)
- Tumor breeches serosa (extends through serosal surface)
- Tumor focally extends into endometrium
- No lymphatic or blood vessel invasion by tumor identified
- Cervix is free of tumor
- Secondary involvement of atrophic ovary by leiomyosarcoma
- No evidence of metastatic tumor involving fallopian tube
- Inactive to weakly proliferative endometrium
- Cervix with atrophic squamous changes, chronic inflammation, squamous metaplasia and nabothian cysts
- Fallopian tube with foci of mullerian (ovarian-like) stroma at fimbriated end
- Paratubal endosalpingiosis and Walthard rests

COMMENT: The tumor exhibits mostly "conventional" spindle cell features, but there are also some pleomorphic tumor cells, a minor myxoid tumor component, and a small subpopulation of tumor cells with cytoplasmic clearing (latter are consistent with a minor component of tumor with features of epithelioid leiomyosarcoma). The tumor exhibits increased mitotic activity with a few atypical mitoses, low to high grade cellular atypia, and areas of necrosis, including so-called coagulative-type tumor cell necrosis. Pathologic tumor stage is assigned as follows: pT2a, NX. A selected section of the primary uterine tumor and sections of tumor involving the right ovary were also reviewed by _____ and _____, who agree with my diagnostic interpretation [IDC2b]. The preliminary findings were conveyed to Dr. _____.

HISTORY:

ICD-O-3
Leiomyosarcoma, NOS 8890/3
Site: uterus C55.9
NOS

[page 2 of 4]
PATIENT:

Postmenopausal bleeding; personal history of breast cancer on Tamoxifen; family history of ovarian cancer

MICROSCOPIC FINDINGS:

See diagnosis.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
Desmin	C16, C17	Smooth muscle cells and many spindle cells in the ovarian stroma exhibit positive staining.
Vimentin	C16	Mesenchymal cells (stromal and smooth muscle cells) exhibit positive staining.
Ki-67 QT	C16	Some (less than 15%) of the neoplastic smooth muscle cells in the ovary exhibit positive nuclear staining.
Actin, smooth muscle	C16, C17	Smooth muscle cells and some ovarian stromal cells exhibit positive staining.
Inhibin	C16, C17	No specific staining is identified.
Ki-67 QT, man	A6	Less than 5% of the epithelial cells in the distal right fallopian tube exhibit positive nuclear staining.
Ki-67 QT, man	C22	Less than 2% of the epithelial cells in the distal left fallopian tube exhibit positive nuclear staining.
P53 QT, man	A6	There are scattered individual epithelial cells and a few short runs of epithelial cells in the distal right fallopian tube that exhibit positive nuclear staining. No runs of 12 or more consecutive positive nuclei are identified, i.e. there is no evidence of a so-called p53 signature profile.
P53 QT, man	C22	Scattered rare epithelial cells in the distal left fallopian tube exhibit positive nuclear staining. No runs of 12 or more consecutive positive nuclei are identified, i.e. there is no evidence of a so-called p53 signature profile.

*These IHC studies were interpreted in conjunction with appropriate positive and negative controls which demonstrated the expected positive and negative reactivity.

GROSS:

A. RIGHT TUBE AND OVARY

Labeled with the patient's name, designated "right tube and ovary", and received in formalin is a 6.6 gram salpingo-oophorectomy specimen. The ovary is about 2.2 x 1.5 x 0.4 cm. The fimbriated fallopian tube is 5.0 cm long, ranges from 0.3 to 0.5 cm in diameter and has a luminal diameter of 0.1 cm.

No gross tumor is seen in the ovary or fallopian tube.

Adhesions are present between the ovary and fallopian tube. The ovary is atrophic and otherwise grossly unremarkable. There is a 0.5 x 0.4 x 0.4 cm unilocular paratubal cyst attached to the distal segment of the fallopian tube. The cyst contains clear fluid. The fallopian tube is otherwise unremarkable.

Fallopian tube and ovary entirely submitted.

Slide key:

A1, A2. Ovary - 4 each

A3. Proximal fallopian tube - 6

[page 3 of 4]
- A4. Mid fallopian tube - 4
- A5. Distal fallopian tube including paratubal cyst - 3
- A6. Fimbriated end - 4

B. UTERINE MASS FOR FROZEN SECTION

Labeled with the patient's name _____ designated "uterine mass for frozen section", and received fresh for intraoperative frozen section evaluation and subsequently fixed in formalin is a 2.0 x 2.0 x 1.5 cm portion of soft tan tissue with focal hemorrhage.

Sectioning reveals tan soft tissue with focal hemorrhage.

Representative sections, including the entire frozen section remnant, are submitted.

Slide key:

- B1. FSB frozen section remnant - 1
- B2. Additional sections - 2

C. UTERUS WITH CERVIX FOR FROZEN SECTION WITH LEFT TUBE AND OVARY

Labeled with the patient's name _____ designated "uterus with cervix for frozen section with left tube and ovary", and received fresh for intraoperative gross evaluation and subsequently fixed in formalin is a 650 gram intact total hysterectomy and left salpingo-oophorectomy specimen. The uterus is about 14.5 x 10.0 x 9.0 cm. The cervical portion of the uterus is 2.3 cm long and up to 3.5 cm in diameter. The endometrial cavity is 4.5 cm long and up to 1.3 cm in width. The endometrial mucosa is up to 0.1 cm in thickness. The muscular uterine wall ranges from 1.5 to 2.5 cm. No vaginal cuff or parametrial tissues are present. The left ovary is about 2.3 x 1.1 x 0.8 cm. The fimbriated left fallopian tube is 5.8 cm long, ranges from 0.3 to 0.4 cm in diameter, and has a maximum luminal diameter of 0.1 cm.

There is a poorly delineated, heterogenous tumor that diffusely involves the myometrium from the lower uterine segment to the fundus in the anterior and posterior segments. The tumor is estimated to be about 13.5 x 9.5 x 9.0 cm in greatest overall dimensions. In the lower uterine segment, the tumor is tan, semi-firm, has a whorled configuration and appears viable. Tan-yellow semi-soft areas that may be necrotic are present in the portion of the tumor in left lateral uterine corpus. The remainder of the tumor is soft, tan, and focally hemorrhagic, and shows additional areas of possible necrosis. No gross tumor is seen in the endometrium or cervix. The tumor protrudes from the left anterolateral serosal surface as a pseudopolypoid 2.5 x 2.3 x 0.9 cm yellow mass, but elsewhere is confined to the uterine wall. The uterine serosa on the left lateral surface is indented, fibrotic, and irregular. The left adnexal structures are adherent to the uterus in the vicinity of tumor and the ovary may be secondarily involved. No gross tumor is seen in the fallopian tube.

No gross pathologic lesions of the endometrium are seen. The cervix is remarkable only for several mucus-filled cysts, the largest of which is about 0.2 cm in diameter. The ovary also shows atrophic changes. No gross pathologic lesions of the fallopian tube (proper) are identified.

Photographs of the specimen are obtained.

Ink key:

- Black - Posterior serosa.
- Blue - Anterior serosa.

The ovary and fallopian tube are each entirely embedded. Representative sections of the uterus, including uterine cervix, are submitted.

Slide key:

- C1. Anterior cervix - 1
- C2. Posterior cervix - 1

[page 4 of 4]
- C3. Anterior lower uterine segment with portion of tumor - 1
C4, C5. Yellow area of uterine tumor extending through serosa (left anterolateral corpus), bisected - 1 each
C6, C7. Anterior corpus, bisected, with viable-appearing tumor - 1 each
C8, C9. Soft area of tumor, anterior corpus, bisected - 1 each
C10. Uterine fundus with focally hemorrhagic tumor - 1
C11. Posterior fundus with viable-appearing tumor - 1
C12, C13. Posterior corpus, bisected, with viable-appearing tumor - 1 each
C14. Posterior left lower uterine segment with viable-appearing tumor - 1
C15. Softer areas of uterine tumor - 2
C16-C18. Ovary in relation to tumor - 4 each
C19. Proximal fallopian tube - 3
C20. Mid fallopian tube - 3
C21. Distal fallopian tube - 3
C22. Fimbriated end of fallopian tube - 3

Gross dictated by

INTRAOPERATIVE CONSULTATION:

OPERATIVE CONSULT (FROZEN):

FSB1 (UTERINE MASS):

- Cellular spindle cell lesion with atypia. Differential includes cellular leiomyoma versus leiomyosarcoma. Defer to permanent

OPERATIVE CONSULT (GROSS)

[SPECIMEN C]:

- No gross endometrial lesion. Myometrial mass. Defer.

[Tumor] saved for research.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
M.D. Electronically signer

SURGICAL PATHOLOGY REPORT

if this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by those immunohistochemical tests have not been cleared or approved by the FDA, and FDA approval is not required.

Source: NCI Genomic Data Commons file 489d81c2-4b4b-44fa-9799-9dcf196aea2e (TCGA-IW-A3M6.4C967429-23AE-4393-B39E-B939AC1AC399.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).